Somatic mutation profile of tumor specimen TCGA-A6-2672-01B (aliquot TCGA-A6-2672-01B-03D-2298-08) from TCGA case TCGA-A6-2672, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 82.8 years (30,237 days).
Specimen TCGA-A6-2672-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98854598-12e3-4238-9ce6-0551601a2765.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2672-11A (Solid Tissue Normal), aliquot TCGA-A6-2672-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07e17e3b-b482-40fc-980b-184e9d34506c

The open-access MAF lists 1,427 somatic variants for this specimen: 1,086 protein-altering or splice-affecting, 317 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 750, Silent 317, Frame Shift Del 188, Frame Shift Ins 63, Nonsense Mutation 36, Splice Site 25, Intron 13, Splice Region 10, In Frame Del 9, RNA 3, 5'Flank 3, 3'UTR 2.

Variants (750 of 1,427; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- BRPF1 | c.2794del p.Q932Sfs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs762904815, COSV57403691; ClinVar: pathogenic; called by mutect2, varscan2
- CFTR | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 54/169 reads (32%) | catalogued as rs121908760, CM950248, COSV50041819, COSV99140454; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- DNAH5 | c.9235C>T p.R3079* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | catalogued as rs1175877764, COSV54263522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 56/203 reads (28%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- KAT6B | c.4379del p.L1460* | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as rs1057517906; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 24/108 reads (22%) | catalogued as rs781585299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYBPC3 | c.1358dup p.V454Cfs*21 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs727503203; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.209+4_209+7del p.X70_splice | Splice Site (DEL) | VAF 44/141 reads (31%) | hotspot (GDC flag); catalogued as rs398123318; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 49/168 reads (29%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WT1 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 231/724 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.495); catalogued as rs121907903, CM041493, CM920718, CM982050, COSV60065677, COSV60065800, COSV60069955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 67/202 reads (33%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCA13 | c.8311C>A p.L2771I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs577917720; called by muse, mutect2, varscan2
- ABCA4 | c.4573C>A p.L1525M | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as CM162859; called by muse, mutect2, varscan2
- ABCA7 | c.5045G>A p.R1682Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs747692429; called by muse, mutect2, varscan2
- ABCB8 | c.1379del p.G460Afs*31 (on ENST00000297504 / NM_001282291.2; = p.G443Afs*31 on NM_007188.5) | Frame Shift Del (DEL) | VAF 80/279 reads (29%) | catalogued as rs1563300045; called by mutect2, pindel, varscan2
- ABCD1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as CD961754, COSV99497822; called by muse, mutect2, varscan2
- AC011462.1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV60531670; called by muse, mutect2, varscan2
- AC127029.3 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); catalogued as rs1375894753; called by muse, mutect2, varscan2
- ACIN1 | c.3344G>T p.R1115L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as COSV52977248, COSV99400505; called by muse, mutect2, varscan2
- ACR | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780358967; called by muse, mutect2, varscan2
- ACTL6A | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99372867; called by muse, mutect2, varscan2
- ACTN1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs372651589; called by muse, mutect2, varscan2
- ACTN4 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs375921941; called by muse, mutect2, varscan2
- ADAM21 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 114/417 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs1259634123; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTS17 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs761568437, COSV51487210; called by muse, mutect2, varscan2
- ADAMTS8 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 116/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs371562238, COSV57291463; called by muse, mutect2, varscan2
- ADCY5 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 114/422 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs771319042, COSV100567953, COSV59195474; called by muse, mutect2, varscan2
- ADCY8 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs183246609, COSV53896645; called by muse, mutect2, varscan2
- ADGRB1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs748739348, COSV60096229; called by mutect2, varscan2
- ADGRG4 | c.7708C>T p.R2570W | Missense Mutation (SNP) | VAF 221/708 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs756624091; called by muse, mutect2, varscan2
- ADGRL3 | c.3052T>G p.F1018V (on ENST00000506720 / NM_001322402.2; = p.F950V on NM_015236.6) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV72231329; called by muse, mutect2, varscan2
- ADORA1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs141819948, COSV99704888; called by muse, mutect2, varscan2
- AEBP1 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV56260665; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs779815391; called by mutect2, varscan2
- AGRN | c.4759G>T p.D1587Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs752862781; called by muse, mutect2, varscan2
- AHDC1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.542); catalogued as rs757919190; called by muse, mutect2, varscan2
- AHNAK2 | c.12950T>C p.I4317T | Missense Mutation (SNP) | VAF 322/856 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as rs1357836754; called by muse, mutect2, varscan2
- AKT1 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62571792, COSV62572815; called by muse, mutect2, varscan2
- AMD1 | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs1188355165; called by muse, mutect2, varscan2
- AMER2 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1202477105; called by muse, mutect2
- ANKRD27 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1487971975; called by muse, mutect2, varscan2
- AP1M2 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.284); catalogued as rs754967797; called by muse, mutect2, varscan2
- AP1M2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257700973; called by muse, mutect2, varscan2
- APBB3 | c.978G>T p.W326C (on ENST00000357560 / NM_133173.2; = p.W333C on NM_006051.3) | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60054557; called by muse, mutect2, varscan2
- APLP1 | c.1777G>A p.G593R (on ENST00000221891 / NM_001024807.3; = p.G592R on NM_005166.4) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1296100771, COSV55707169; called by muse, mutect2, varscan2
- APOB | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs375294575, COSV51959060; called by muse, mutect2, varscan2
- ARHGAP18 | c.1562T>G p.L521R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100936028, COSV63763474; called by muse, mutect2, varscan2
- ARHGEF5 | c.3622G>A p.A1208T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs753105342; called by mutect2, varscan2
- ARSB | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs138643812, COSV53730252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF7 | c.1361G>A p.R454H (on ENST00000548446 / NM_001366555.2; = p.R443H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as rs560379424; called by muse, varscan2
- ATF7 | c.680C>T p.P227L (on ENST00000548446 / NM_001366555.2; = p.P216L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs978219733, COSV60643919; called by muse, mutect2, varscan2
- ATP13A1 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs529487345; called by muse, mutect2, varscan2
- ATP2A3 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776362490, COSV59227981; called by muse, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | catalogued as rs769726180; called by mutect2, varscan2
- B2M | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV62562840, COSV62562870, COSV62563658; called by muse, mutect2, varscan2
- B4GALNT4 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1163396980, COSV100327933, COSV57326323; called by muse, mutect2, varscan2
- BAHCC1 | c.7528C>T p.R2510W | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57027247; called by muse, mutect2, varscan2
- BARHL1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 152/543 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1015080616, COSV55037915; called by muse, mutect2, varscan2
- BAZ1A | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs560209924, COSV62411199, COSV62411670; called by muse, mutect2, varscan2
- BAZ2B | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as rs948120805; called by muse, varscan2
- BAZ2B | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs1446087820; called by muse, varscan2
- BEST3 | c.1219A>G p.S407G | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58305941; called by muse, mutect2, varscan2
- BLM | c.2351A>G p.Y784C | Missense Mutation (SNP) | VAF 125/382 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs753635754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 49/204 reads (24%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRS3 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV65710734; called by muse, mutect2, varscan2
- C10orf90 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386226244, COSV52951341; called by muse, mutect2, varscan2
- C17orf97 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.638); catalogued as rs199777787; called by muse, varscan2
- C1orf115 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs753438102, COSV54274592; called by muse, mutect2, varscan2
- C2CD5 | c.2084T>C p.L695P | Missense Mutation (SNP) | VAF 136/451 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100448619; called by muse, mutect2, varscan2
- C5AR2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.883); catalogued as rs1200532265; called by muse, mutect2, varscan2
- CACHD1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs915706137, COSV51553672; called by muse, mutect2, varscan2
- CAMTA1 | c.1323G>C p.K441N | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV57928451; called by muse, mutect2, varscan2
- CAND1 | c.2938T>A p.Y980N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV73389622; called by muse, varscan2
- CAPN10 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV54380013; called by muse, mutect2, varscan2
- CARD14 | c.1437del p.S480Afs*49 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs780143594; called by mutect2, varscan2
- CARM1 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs765573504; called by muse, mutect2, varscan2
- CASK | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs771368987, COSV100587107; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CASZ1 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749998383; called by muse, mutect2, varscan2
- CBX4 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 30/916 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1262334964, COSV53965674; called by muse, mutect2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 104/338 reads (31%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC102A | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs578064250; called by muse, mutect2, varscan2
- CCDC15 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs755396322; called by muse, varscan2
- CCDC15 | c.581dup p.S196Ifs*6 | Frame Shift Ins (INS) | VAF 23/77 reads (30%) | catalogued as rs759789184; called by mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 51/209 reads (24%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC33 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs749495036, COSV51498974; called by muse, mutect2, varscan2
- CCDC86 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs370580113; called by muse, mutect2, varscan2
- CCN4 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV51531200; called by muse, mutect2, varscan2
- CCNF | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV53540411, COSV53543489; called by muse, mutect2, varscan2
- CD2AP | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV63763349; called by muse, mutect2, varscan2
- CD4 | c.498dup p.K167Efs*13 | Frame Shift Ins (INS) | VAF 50/154 reads (32%) | catalogued as rs781937995; called by mutect2, varscan2
- CD53 | c.252G>A p.S84= | Splice Region (SNP) | VAF 95/314 reads (30%) | catalogued as rs748933796, COSV104375525; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 77/316 reads (24%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDC25C | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776347990, COSV60399360; called by muse, mutect2, varscan2
- CDC42BPA | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs757075704; called by muse, mutect2, varscan2
- CDCA4 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs1206804327; called by muse, mutect2, varscan2
- CDH12 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs1348151397, COSV66437667; called by muse, mutect2, varscan2
- CDH18 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99933993; called by muse, mutect2, varscan2
- CDH19 | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV50957029; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1112G>A p.R371H (on ENST00000357886 / NM_001365728.1; = p.R357H on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745597149, COSV59428575, COSV59429089; called by muse, mutect2, varscan2
- CELSR3 | c.2386G>A p.G796S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs958600945, COSV51142237; called by muse, mutect2, varscan2
- CEP68 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs921894381, COSV53123610; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFTR | c.53+2T>C p.X18_splice | Splice Site (SNP) | VAF 58/149 reads (39%) | catalogued as CS136998; called by muse, mutect2, varscan2
- CHD5 | c.3527G>A p.G1176D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52424544; called by muse, mutect2, varscan2
- CHD5 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as rs751016124, COSV52409139; called by muse, mutect2, varscan2
- CHIT1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs768872163, COSV55149904; called by muse, mutect2, varscan2
- CHRNE | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 105/332 reads (32%) | catalogued as rs1278514080, COSV53419458; called by muse, mutect2, varscan2
- CHST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57323162; called by muse, mutect2, varscan2
- CHST6 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1402160505; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 31/60 reads (52%) | catalogued as rs778982759; called by mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLCN7 | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | catalogued as COSV51969394; called by muse, mutect2, varscan2
- CLEC14A | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 202/691 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs937080683; called by muse, mutect2, varscan2
- CLN6 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs781133812, COSV51117762; called by muse, mutect2, varscan2
- CMTM6 | c.213del p.F71Lfs*4 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs1167303901; called by mutect2, pindel, varscan2
- CMTR2 | c.1651dup p.S551Ffs*2 | Frame Shift Ins (INS) | VAF 42/148 reads (28%) | catalogued as rs1379046770; called by mutect2, pindel, varscan2
- CNNM2 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV63996492; called by muse, mutect2, varscan2
- CNOT1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751379476; called by muse, mutect2, varscan2
- CNOT7 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 87/354 reads (25%) | catalogued as COSV63517826, COSV63518163; called by muse, mutect2, varscan2
- COL11A1 | c.4410del p.G1471Vfs*27 | Frame Shift Del (DEL) | VAF 82/287 reads (29%) | catalogued as COSV62178034; called by mutect2, pindel, varscan2
- COL5A1 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1448698493, COSV65675296; called by muse, mutect2, varscan2
- COL7A1 | c.8025G>T p.K2675N | Missense Mutation (SNP) | VAF 62/230 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56477326, COSV99866385; called by muse, mutect2, varscan2
- COX7A2L | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs1010774893, COSV52242670; called by muse, mutect2, varscan2
- CPSF7 | c.350A>C p.E117A (on ENST00000394888 / NM_001136040.4; = p.E160A on NM_024811.4) | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV104414625; called by muse, mutect2, varscan2
- CPXCR1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99342386; called by muse, mutect2, varscan2
- CPXM2 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 156/564 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV99583679; called by muse, mutect2, varscan2
- CRTC3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 52/1510 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV99185608; called by muse, mutect2
- CRYBG1 | c.5132A>G p.N1711S | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as rs140451533; called by muse, mutect2, varscan2
- CSMD1 | c.2894A>G p.H965R (on ENST00000520002; = p.H964R on NM_033225.6) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1157362726; called by muse, mutect2, varscan2
- CSPG4 | c.6686T>C p.M2229T | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs754919573; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 114/424 reads (27%) | catalogued as rs767756120; called by mutect2, varscan2
- CTC1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs368398609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs775874494, COSV50466689; called by muse, mutect2, varscan2
- CUL7 | c.2006T>C p.L669P | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54822326; called by muse, mutect2, varscan2
- CYP19A1 | c.1483A>T p.R495* | Nonsense Mutation (SNP) | VAF 165/541 reads (30%) | catalogued as COSV53059026, COSV53061515; called by muse, mutect2, varscan2
- DCAF4 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370177630; called by muse, mutect2, varscan2
- DCAF5 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs1470338939, COSV58459995; called by muse, mutect2, varscan2
- DCLRE1A | c.1032dup p.K345* | Frame Shift Ins (INS) | VAF 49/186 reads (26%) | catalogued as rs751315517; called by mutect2, varscan2
- DCST2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376847671, COSV55055109; called by muse, mutect2, varscan2
- DCUN1D4 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58125306; called by muse, varscan2
- DENND1A | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749587293, COSV65330210; called by muse, mutect2, varscan2
- DFFB | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs375484294; called by muse, mutect2, varscan2
- DHCR7 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs779222334, COSV62795722; ClinVar: uncertain significance; called by muse, varscan2
- DHX29 | c.2480A>G p.Q827R | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1453711185; called by muse, mutect2, varscan2
- DIAPH1 | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs373654027; called by muse, mutect2, varscan2
- DIDO1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs777989220; called by muse, mutect2, varscan2
- DIP2C | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55160237; called by muse, mutect2, varscan2
- DLGAP2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV70097249; called by muse, mutect2, varscan2
- DMD | c.4141T>G p.L1381V | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100820323, COSV63732284; called by muse, mutect2, varscan2
- DMPK | c.87_89del p.L30del | In Frame Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs759918150; called by mutect2, varscan2
- DNA2 | c.2326del p.L776Ffs*9 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | catalogued as COSV64428742; called by pindel, varscan2
- DNAH10 | c.12878C>T p.S4293L (on ENST00000409039; = p.S4232L on NM_207437.3) | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs748316604, COSV53019881; called by muse, mutect2, varscan2
- DNAI2 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs776802277, COSV56761251; called by muse, mutect2, varscan2
- DNAJB14 | c.618del p.F206Lfs*48 | Frame Shift Del (DEL) | VAF 62/200 reads (31%) | catalogued as rs1222627541, COSV62033022; called by mutect2, pindel, varscan2
- DNAJC21 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV57762786; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK6 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs780042576, COSV66933129, COSV66938262; called by muse, mutect2, varscan2
- DOLK | c.1114T>G p.F372V | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs146395561, COSV58282823; called by muse, mutect2, varscan2
- DRG2 | c.541-2A>G p.X181_splice | Splice Site (SNP) | VAF 29/107 reads (27%) | catalogued as COSV56728630; called by muse, mutect2, varscan2
- DRP2 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65809206; called by muse, mutect2, varscan2
- DSCAML1 | c.980C>T p.P327L (on ENST00000321322; = p.P267L on NM_020693.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs763722217, COSV58397842, COSV58400217; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 56/193 reads (29%) | catalogued as rs35805169; called by mutect2, pindel, varscan2
- EBF2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1414125429; called by muse, mutect2, varscan2
- ECT2 | c.1462C>T p.R488C (on ENST00000392692 / NM_001349098.2; = p.R457C on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs748437185; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 48/283 reads (17%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EGFL6 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 142/452 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1376908510; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as COSV99653876; called by mutect2, pindel, varscan2
- EHBP1L1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764167148, COSV57079108; called by muse, mutect2, varscan2
- ELOVL3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774432163, COSV64174285; called by muse, mutect2, varscan2
- ELP1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766255360, COSV65896090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | catalogued as rs770453803; called by mutect2, varscan2
- ENTPD8 | c.1382G>A p.R461Q (on ENST00000371506 / NM_001033113.2; = p.R424Q on NM_198585.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs768017419; called by muse, mutect2, varscan2
- EPX | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs577707337, COSV56597681; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 38/186 reads (20%) | catalogued as rs768793415; called by mutect2, varscan2
- EREG | c.132_133del p.S45* | Frame Shift Del (DEL) | VAF 127/494 reads (26%) | catalogued as COSV55262680; called by mutect2, pindel, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by muse, mutect2, varscan2
- ESRP1 | c.996del p.L333Sfs*55 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as COSV64410340; called by mutect2, pindel, varscan2
- ESRP1 | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV64408871; called by muse, varscan2
- ESRRG | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1476998088, COSV63170974, COSV63179370; called by muse, mutect2, varscan2
- ETV6 | c.775C>G p.R259G | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs141868934, COSV101122819, COSV67151457, COSV67154509; called by muse, varscan2
- EVC | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 336/1105 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202026284, COSV53830883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.3300dup p.E1101Rfs*17 | Frame Shift Ins (INS) | VAF 29/141 reads (21%) | catalogued as rs1302660801; called by mutect2, pindel, varscan2
- FAM151B | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963367412; called by muse, mutect2, varscan2
- FAM83C | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs377103295; called by muse, mutect2, varscan2
- FANK1 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as rs373547952; called by muse, varscan2
- FAT3 | c.9613G>A p.V3205M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780817713, COSV53143869, COSV99970894; called by muse, mutect2, varscan2
- FAT3 | c.11591G>A p.R3864H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372126226; called by muse, mutect2, varscan2
- FAT4 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV101271691; called by muse, mutect2, varscan2
- FBN3 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV54469599; called by muse, mutect2, varscan2
- FBXL18 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); catalogued as rs766143098; called by muse, mutect2, varscan2
- FCN2 | c.941A>G p.*314Wext*13 | Nonstop Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as rs1402966593; called by muse, mutect2, varscan2
- FGD6 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149533885; called by muse, mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | catalogued as rs766041577; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FNDC1 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99794584; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 80/119 reads (67%) | catalogued as COSV56761013; called by mutect2, varscan2
- FOXO4 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as rs1231541956, COSV58575382; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 42/151 reads (28%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMPD1 | c.3529C>T p.P1177S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs927677060, COSV66699056; called by muse, mutect2, varscan2
- FSTL5 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs375718347; called by muse, mutect2, varscan2
- GAL3ST2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769648241, COSV51951004; called by muse, mutect2, varscan2
- GDF10 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs894818813; called by muse, mutect2, varscan2
- GIMAP1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs1408844890, COSV56189033; called by muse, mutect2, varscan2
- GJA3 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53833967, COSV53835283; called by muse, mutect2
- GJD4 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs201736651; called by muse, varscan2
- GNA11 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV50056129; called by muse, mutect2, varscan2
- GNL3 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 67/223 reads (30%) | catalogued as rs745733070, COSV56478279; called by muse, mutect2, varscan2
- GORASP1 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1416002288, COSV57188171; called by muse, mutect2, varscan2
- GPR101 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV53240549; called by muse, mutect2, varscan2
- GPR149 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs761233578, COSV67667000; called by muse, mutect2, varscan2
- GPR50 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 99/331 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370344133, COSV54440264; called by muse, varscan2
- GPR50 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs372169533, COSV54436908; called by muse, varscan2
- GRID1 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 232/752 reads (31%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs771133372; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 60/200 reads (30%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); catalogued as rs368604495; called by muse, varscan2
- GSX2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58842426; called by muse, mutect2, varscan2
- GUCY2D | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs751520851; called by muse, varscan2
- H1-5 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV58900773; called by muse, mutect2, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 84/253 reads (33%) | catalogued as rs768797944; called by mutect2, varscan2
- HAGHL | c.832T>C p.W278R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs772404351; called by muse, mutect2, varscan2
- HAS1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1309628554, COSV55789861; called by muse, mutect2, varscan2
- HDAC7 | c.425G>A p.S142N (on ENST00000427332; = p.S181N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50410034; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | catalogued as COSV100625709; called by mutect2, varscan2
- HECW2 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.616); catalogued as rs1188606678, COSV53671813; called by muse, mutect2, varscan2
- HELZ2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs374328737; called by mutect2, varscan2
- HERC1 | c.12866C>T p.A4289V | Missense Mutation (SNP) | VAF 78/447 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV71248974; called by muse, mutect2, varscan2
- HERC4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1164946098, COSV53268584; called by muse, mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 123/519 reads (24%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HRNR | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 181/627 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.123); catalogued as rs375817815; called by muse, mutect2, varscan2
- HSPG2 | c.9970G>A p.G3324R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294413650; called by muse, mutect2, varscan2
- IFIH1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs186942719, COSV55125491; called by muse, mutect2, varscan2
- IFNAR2 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV59750202; called by muse, mutect2, varscan2
- IGHG2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs375068368; called by muse, mutect2, varscan2
- IGSF9B | c.2335T>A p.S779T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs781574279; called by mutect2, varscan2
- IHH | c.1135del p.E379Rfs*18 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as COSV55393105; called by mutect2, pindel, varscan2
- IL1R2 | c.696dup p.E233Rfs*27 | Frame Shift Ins (INS) | VAF 46/198 reads (23%) | catalogued as rs772911553; called by mutect2, varscan2
- IL1RL1 | c.1589A>G p.H530R | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs779804857; called by muse, mutect2
- IL21R | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.312); catalogued as rs913538510, COSV104402061, COSV61971812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPG1 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV64062141; called by muse, mutect2, varscan2
- INPPL1 | c.2920G>C p.A974P | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53353125; called by muse, mutect2, varscan2
- INTS5 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs150766238; called by muse, mutect2, varscan2
- IPO13 | c.2028C>T p.P676= | Splice Region (SNP) | VAF 26/116 reads (22%) | catalogued as rs146256412; called by muse, mutect2, varscan2
- IPO13 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 335/1126 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as rs1423130639, COSV64893553; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | catalogued as rs762230866, COSV99339624; called by mutect2, pindel, varscan2
- ITGA9 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV53252078; called by muse, mutect2, varscan2
- ITPR3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406344; called by muse, mutect2, varscan2
- IWS1 | c.1745del p.K582Sfs*4 | Frame Shift Del (DEL) | VAF 118/179 reads (66%) | catalogued as rs1558747232; called by mutect2, varscan2
- JAKMIP2 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 147/480 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs746010111; called by muse, mutect2, varscan2
- JAM3 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); catalogued as rs762126235, COSV54449932; called by muse, mutect2, varscan2
- KATNIP | c.3491C>T p.T1164M | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752581000; called by muse, mutect2, varscan2
- KCNS2 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54641257; called by muse, varscan2
- KDM4B | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV50223377; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 58/150 reads (39%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM6B | c.2251G>A p.V751I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs778356472, COSV54688025; called by mutect2, varscan2
- KIF7 | c.1702dup p.L568Pfs*21 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | catalogued as rs772716663; called by mutect2, pindel, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs749011008; called by mutect2, varscan2
- KLHL36 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs140762792; called by muse, mutect2, varscan2
- KLK5 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV60451206; called by muse, mutect2, varscan2
- KMT2D | c.16228G>T p.G5410W | Missense Mutation (SNP) | VAF 111/330 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56432991; called by muse, mutect2, varscan2
- KPTN | c.1070T>G p.L357R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1299553888; called by muse, mutect2, varscan2
- KRT33A | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 142/465 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs552619720, COSV50374101; called by muse, mutect2, varscan2
- KRT85 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.191); catalogued as rs370269453; called by muse, mutect2, varscan2
- KRT9 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 78/194 reads (40%) | PolyPhen benign (0.005); catalogued as rs776803750; called by muse, mutect2, varscan2
- L1TD1 | c.337dup p.T113Nfs*13 | Frame Shift Ins (INS) | VAF 84/331 reads (25%) | catalogued as rs753466100; called by mutect2, pindel, varscan2
- L3MBTL2 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs555547448, COSV53435874; called by muse, mutect2, varscan2
- LAMB1 | c.1181T>C p.F394S | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55970612; called by muse, mutect2, varscan2
- LILRB4 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs370306475; called by muse, mutect2, varscan2
- LOXL4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53259507; called by muse, mutect2, varscan2
- LRP1 | c.12619G>A p.G4207S | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs371843269; called by muse, mutect2, varscan2
- LRP5 | c.4096G>A p.D1366N | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs779534615; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRN4 | c.2170T>C p.Y724H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs763288561; called by muse, mutect2, varscan2
- LTBP1 | c.1228G>T p.G410C (on ENST00000404816 / NM_206943.4; = p.G84C on NM_000627.4) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63187532; called by muse, mutect2, varscan2
- LUC7L3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1235636727, COSV53586572; called by muse, mutect2
- MACF1 | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 110/329 reads (33%) | catalogued as rs769186880; called by muse, mutect2, varscan2
- MAF | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.133); catalogued as rs878873480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN1C1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs527879949; called by muse, mutect2, varscan2
- MAN2A2 | c.3061G>A p.A1021T | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773581061; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 93/302 reads (31%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP7D1 | c.1492del p.R498Efs*77 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | catalogued as COSV100294600; called by mutect2, pindel, varscan2
- MAPRE3 | c.120A>G p.S40= | Splice Region (SNP) | VAF 76/210 reads (36%) | catalogued as COSV51866777, COSV51869452; called by muse, mutect2, varscan2
- MAT1A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1038206403, COSV64745420; called by muse, mutect2, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 72/217 reads (33%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MBP | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs529411261, COSV62830682; called by muse, mutect2, varscan2
- MBTPS1 | c.1790del p.N597Mfs*9 | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | catalogued as rs780087229; called by pindel, varscan2
- MESD | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55725178; called by mutect2, varscan2
- METTL21C | c.536del p.N179Tfs*13 | Frame Shift Del (DEL) | VAF 44/225 reads (20%) | catalogued as rs1464214036; called by mutect2, pindel, varscan2
- METTL7A | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 102/348 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs756853071, COSV59840491; called by muse, varscan2
- MFSD6L | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1485640478; called by muse, mutect2, varscan2
- MGA | c.5407C>T p.H1803Y (on ENST00000219905 / NM_001164273.1; = p.H1594Y on NM_001080541.2) | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54966454; called by muse, mutect2, varscan2
- MGA | c.7980G>T p.E2660D (on ENST00000219905 / NM_001164273.1; = p.E2451D on NM_001080541.2) | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99578746; called by muse, mutect2, varscan2
- MGAT5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs145359732; called by muse, varscan2
- MIER3 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 132/540 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV61229335; called by muse, mutect2, varscan2
- MINAR1 | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV59586897; called by muse, mutect2, varscan2
- MINK1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61792504; called by muse, mutect2, varscan2
- MLEC | c.226del p.V76Wfs*9 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as COSV57329487; called by mutect2, pindel, varscan2
- MPZL1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs367767112, COSV63256265; called by muse, mutect2, varscan2
- MRPL2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs532734983, COSV52436506; called by muse, mutect2, varscan2
- MRPS18B | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 145/543 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760083966, COSV52542717; called by muse, mutect2, varscan2
- MRPS5 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs142603460; called by muse, mutect2, varscan2
- MSANTD4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs754826530; called by muse, mutect2, varscan2
- MTA2 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated, low confidence (0.95); PolyPhen possibly damaging (0.899); catalogued as rs1008868253; called by muse, mutect2, varscan2
- MTHFSD | c.663G>A p.M221I (on ENST00000360900 / NM_001159377.2; = p.M220I on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs371515815; called by muse, mutect2, varscan2
- MUC17 | c.11198C>A p.S3733* | Nonsense Mutation (SNP) | VAF 249/794 reads (31%) | catalogued as COSV60296811; called by muse, mutect2, varscan2
- MUC5B | c.10532G>A p.S3511N | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1469407804; called by muse, mutect2, varscan2
- MX1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762946488, COSV55817619; called by muse, mutect2, varscan2
- MYCBP2 | c.3149G>A p.G1050D (on ENST00000357337; = p.G1088D on NM_015057.5) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV62017156; called by muse, mutect2, varscan2
- MYH15 | c.40dup p.W14Lfs*24 | Frame Shift Ins (INS) | VAF 31/138 reads (22%) | catalogued as rs752868848; called by mutect2, varscan2
- MYH2 | c.1897+2T>C p.X633_splice | Splice Site (SNP) | VAF 176/629 reads (28%) | catalogued as COSV99820109; called by muse, mutect2, varscan2
- MYLK | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745547260; called by muse, mutect2, varscan2
- MYLPF | c.435dup p.D146Rfs*50 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | catalogued as rs754372271; called by mutect2, varscan2
- MYO1B | c.2295+1G>A p.X765_splice | Splice Site (SNP) | VAF 83/310 reads (27%) | catalogued as COSV58432070; called by muse, mutect2, varscan2
- MYO5A | c.2504A>G p.K835R | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1363612638; called by muse, mutect2, varscan2
- MYOF | c.2691A>T p.E897D | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.718); catalogued as COSV63710983; called by muse, mutect2, varscan2
- MYOM3 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs753277372; called by muse, mutect2, varscan2
- NALCN | c.2782T>A p.F928I | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV99078466; called by muse, mutect2, varscan2
- NAV3 | c.1199dup p.Q401Afs*8 | Frame Shift Ins (INS) | VAF 60/205 reads (29%) | catalogued as rs772313322; called by mutect2, pindel, varscan2
- NBEA | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.269); catalogued as rs747037643, COSV59807762, COSV59822982; called by muse, mutect2, varscan2
- NBEA | c.7234C>T p.R2412* | Nonsense Mutation (SNP) | VAF 176/350 reads (50%) | catalogued as COSV59795311; called by muse, varscan2
- NCKAP5 | c.5506G>T p.G1836* | Nonsense Mutation (SNP) | VAF 49/507 reads (10%) | catalogued as rs368736527; called by muse, mutect2, varscan2
- NCOR2 | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs756364272, COSV62296756; called by muse, mutect2, varscan2
- NCSTN | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV54191995; called by muse, mutect2, varscan2
- NEDD4L | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs748006260, COSV56842411; called by muse, mutect2, varscan2
- NEURL4 | c.4343G>A p.R1448H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as rs778818175; called by muse, varscan2
- NEUROD4 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 475/1634 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as rs1231490237, COSV54471998; called by muse, mutect2, varscan2
- NFKBIB | c.896_897insA p.E300* | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | catalogued as COSV58005444; called by mutect2, pindel, varscan2
- NGLY1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as rs142766875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHS | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1051206612, COSV101196537; called by muse, mutect2, varscan2
- NICN1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.121); catalogued as rs998001987, COSV56468669; called by muse, mutect2, varscan2
- NLRP2 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs144271525; called by muse, mutect2, varscan2
- NOL7 | c.714dup p.Q239Tfs*7 | Frame Shift Ins (INS) | VAF 26/72 reads (36%) | catalogued as rs544905440; called by mutect2, varscan2
- NOM1 | c.2116T>C p.F706L | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV51982686; called by muse, mutect2, varscan2
- NOS1 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as rs1387099412; called by muse, mutect2, varscan2
- NOTCH3 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as rs1451498063; called by muse, mutect2, varscan2
- NPY | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1388032616, COSV54215104; called by muse, mutect2, varscan2
- NR0B1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV66764375; called by muse, mutect2, varscan2
- NR3C2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs749442977, COSV60991718; called by muse, mutect2, varscan2
- NR6A1 | c.1166A>G p.Y389C (on ENST00000487099 / NM_033334.4; = p.Y384C on NM_001489.5) | Missense Mutation (SNP) | VAF 160/486 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60635534; called by muse, mutect2, varscan2
- NRF1 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 59/227 reads (26%) | catalogued as COSV56217093; called by muse, mutect2, varscan2
- NT5C1B | c.1622C>T p.A541V (on ENST00000359846 / NM_001199086.2; = p.A481V on NM_033253.4) | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58399261; called by muse, mutect2, varscan2
- NUAK2 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1363445242, COSV65681160; called by muse, varscan2
- NUBP1 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV51595854; called by muse, mutect2, varscan2
- NUMA1 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV61191434; called by muse, mutect2, varscan2
- NUMA1 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.895); catalogued as rs766682349; called by muse, mutect2, varscan2
- NYAP1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.801); catalogued as rs574707021, COSV55720687; called by muse, mutect2, varscan2
- OAS3 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs78396126, COSV99966447; called by muse, varscan2
- OR13C3 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 106/383 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs147645466; called by muse, mutect2, varscan2
- OR4D1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs758816903, COSV52125505; called by muse, mutect2, varscan2
- OR4K5 | c.807del p.K269Nfs*14 | Frame Shift Del (DEL) | VAF 74/295 reads (25%) | catalogued as rs775993125; called by mutect2, varscan2
- OR5D16 | c.180del p.M61Cfs*22 | Frame Shift Del (DEL) | VAF 111/477 reads (23%) | catalogued as COSV65721467; called by mutect2, pindel, varscan2
- OR5M1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs553800236, COSV101591544; called by muse, mutect2, varscan2
- PAGE4 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV54334482; called by muse, mutect2, varscan2
- PAK2 | c.1462A>G p.R488G | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59082089; called by muse, mutect2, varscan2
- PANK3 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.292); catalogued as COSV53325549; called by muse, mutect2, varscan2
- PCDH10 | c.3076C>T p.R1026* | Nonsense Mutation (SNP) | VAF 156/553 reads (28%) | catalogued as COSV52093580; called by muse, mutect2, varscan2
- PCDHB8 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.017); catalogued as rs782043465; called by muse, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 118/388 reads (30%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCID2 | c.818del p.K273Sfs*4 | Frame Shift Del (DEL) | VAF 101/486 reads (21%) | catalogued as rs760522684; called by mutect2, pindel, varscan2
- PCNX1 | c.3604del p.C1202Vfs*4 | Frame Shift Del (DEL) | VAF 90/308 reads (29%) | catalogued as COSV99456874; called by mutect2, pindel, varscan2
- PDCD6 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs139334790; called by muse, varscan2
- PDIA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs1037921792, COSV51986209, COSV99249555; called by muse, mutect2, varscan2
- PDZRN4 | c.2953A>C p.I985L (on ENST00000402685 / NM_001164595.2; = p.I727L on NM_013377.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54218224; called by muse, mutect2, varscan2
- PEAK1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757079829; called by muse, mutect2, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | catalogued as rs765092936; called by mutect2, pindel, varscan2
- PGAP6 | c.483del p.S162Hfs*7 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs777809748; called by mutect2, pindel, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs769717544; called by mutect2, varscan2
- PITPNM2 | c.3170C>T p.T1057M | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54909246; called by muse, mutect2, varscan2
- PITPNM2 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as COSV54909255; called by muse, mutect2, varscan2
- PLCE1 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99592927; called by muse, mutect2, varscan2
- PLCH2 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775310342; called by muse, varscan2
- PLD1 | c.577del p.M193Cfs*16 | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | catalogued as COSV60574024; called by mutect2, varscan2
- PLIN4 | c.769G>A p.V257I (on ENST00000301286; = p.V272I on NM_001367868.2) | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs1250787079; called by muse, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB1 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs561091722, COSV56491711; called by muse, mutect2, varscan2
- PMEL | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV59384283; called by muse, mutect2, varscan2
- PNLDC1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs145458684, COSV99277898; called by muse, mutect2, varscan2
- PNMT | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs772028272, COSV54092540; called by muse, mutect2, varscan2
- PODN | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as rs768589887; called by muse, varscan2
- POLE2 | c.783del p.F261Lfs*9 | Frame Shift Del (DEL) | VAF 76/264 reads (29%) | catalogued as rs766106997; called by mutect2, varscan2
- POLG | c.975dup p.T326Hfs*62 | Frame Shift Ins (INS) | VAF 31/105 reads (30%) | catalogued as rs752172363; called by mutect2, pindel, varscan2
- POLH | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1401579662; called by muse, mutect2, varscan2
- POLR3E | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs370651948; called by muse, mutect2, varscan2
- POPDC2 | c.1009+2T>C p.X337_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV51741881; called by muse, mutect2
- POU2F2 | c.187-3dup | Splice Region (INS) | VAF 30/112 reads (27%) | catalogued as rs761526279; called by mutect2, varscan2
- PPAT | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs1476597586; called by muse, mutect2, varscan2
- PPFIBP1 | c.2916A>G p.I972M (on ENST00000318304 / NM_177444.3; = p.I966M on NM_003622.4) | Missense Mutation (SNP) | VAF 164/535 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190705912; called by muse, mutect2, varscan2
- PPID | c.399dup p.I134Yfs*21 | Frame Shift Ins (INS) | VAF 56/203 reads (28%) | catalogued as rs1456058528; called by mutect2, pindel, varscan2
- PPP1R17 | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.015); catalogued as COSV59610641; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs1365223299; called by mutect2, varscan2
- PRKDC | c.10322C>T p.A3441V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs757868901, COSV100038854, COSV58051105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF6 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs538462570, COSV99413149; called by muse, mutect2, varscan2
- PRR5L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.483); catalogued as rs149927791; called by muse, mutect2, varscan2
- PSKH1 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180232058, COSV52123470; called by muse, mutect2, varscan2
- PTH1R | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1375868219; called by muse, mutect2, varscan2
- PTPN1 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs138343840, COSV99247376; called by muse, mutect2, varscan2
- PTPN3 | c.2649G>A p.M883I | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV52710657; called by muse, mutect2, varscan2
- PTPRF | c.4912G>A p.A1638T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs541451200; called by muse, mutect2, varscan2
- PTPRT | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61965720; called by muse, varscan2
- RAD9A | c.1129del p.Q377Rfs*20 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs772325521; called by mutect2, pindel, varscan2
- RANBP3 | c.1144C>T p.R382W (on ENST00000340578 / NM_007322.3; = p.R377W on NM_003624.3) | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs753525599; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs773370779, COSV99532335; called by pindel, varscan2
- RAVER1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50330088; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 76/260 reads (29%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBBP8NL | c.432del p.S145Hfs*65 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs749848235; called by mutect2, varscan2
- RBFOX1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 113/374 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs754708372, COSV60976264; called by muse, mutect2, varscan2
- RBM27 | c.364del p.Q122Rfs*55 | Frame Shift Del (DEL) | VAF 99/449 reads (22%) | catalogued as COSV99505893; called by mutect2, pindel, varscan2
- REV1 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1371245146, COSV51488814; called by muse, mutect2
- RGL4 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as rs773950515; called by muse, mutect2, varscan2
- RGS19 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1202226228, COSV58657341; called by muse, mutect2
- RHBDF1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs752626909; called by muse, mutect2, varscan2
- RIBC1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs782705066; called by muse, mutect2, varscan2
- RIF1 | c.7075A>G p.R2359G | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1458600291; called by muse, mutect2, varscan2
- RNASE10 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs375918997; called by muse, mutect2, varscan2
- RNF213 | c.12149C>T p.A4050V | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs774588883, COSV60391833; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 24/107 reads (22%) | catalogued as rs745519558; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 52/155 reads (34%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL22L1 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382560197; called by muse, mutect2, varscan2
- RPTOR | c.3770C>T p.T1257M | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1212387005, COSV60807361; called by muse, mutect2
- RREB1 | c.2560G>T p.G854C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs752135597; called by muse, varscan2
- RRP1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs768764518; called by muse, mutect2, varscan2
- RUNX1T1 | c.1111del p.T371Qfs*8 (on ENST00000265814 / NM_001198628.1; = p.T344Qfs*8 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 89/316 reads (28%) | catalogued as COSV56164530; called by mutect2, pindel, varscan2
- SACS | c.3303G>T p.K1101N | Missense Mutation (SNP) | VAF 170/749 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1278581093; called by muse, mutect2, varscan2
- SALL2 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs538393267, COSV58105971; called by muse, mutect2, varscan2
- SAMD7 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs201077493; called by muse, mutect2, varscan2
- SAMD8 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs773128897, COSV101013984; called by muse, mutect2, varscan2
- SASH1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs139081709; called by muse, mutect2, varscan2
- SCAF1 | c.3475C>A p.P1159T | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV59191499; called by muse, varscan2
- SCAPER | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 39/175 reads (22%) | catalogued as rs1302842375; called by muse, mutect2, varscan2
- SCN5A | c.5143G>T p.G1715C (on ENST00000333535 / NM_198056.3; = p.G1714C on NM_000335.5) | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61124866; called by muse, mutect2, varscan2
- SCNN1A | c.1351A>C p.S451R | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV57437492; called by muse, mutect2, varscan2
- SETD2 | c.6035T>G p.L2012R | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57452565; called by muse, mutect2, varscan2
- SGSM1 | c.3404G>A p.R1135Q (on ENST00000400359 / NM_001039948.4; = p.R1074Q on NM_133454.3) | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV68514425; called by muse, mutect2, varscan2
- SHANK1 | c.6137C>T p.S2046L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1258374193, COSV53249461; called by muse, mutect2, varscan2
- SHOC1 | c.2147del p.K716Sfs*16 | Frame Shift Del (DEL) | VAF 82/363 reads (23%) | catalogued as COSV59503990; called by mutect2, pindel, varscan2
- SLC12A1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs373101131; called by muse, mutect2, varscan2
- SLC12A7 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as rs373980691; called by muse, varscan2
- SLC22A1 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs756880870; called by muse, varscan2
- SLC22A11 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140236068; called by muse, varscan2
- SLC22A7 | c.808C>A p.P270T (on ENST00000372585 / NM_153320.2; = p.P268T on NM_006672.3) | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV101000850; called by muse, mutect2, varscan2
- SLC27A1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1010005019; called by muse, mutect2, varscan2
- SLC2A10 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs774497964, COSV63716048, COSV63716497; ClinVar: likely benign; called by muse, varscan2
- SLC35B4 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 79/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762326247, COSV65985434; called by muse, mutect2, varscan2
- SLC39A10 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs778580688, COSV62767732; called by muse, varscan2
- SLC41A3 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 130/451 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59990735; called by muse, mutect2, varscan2
- SLC4A3 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763838027; called by muse, mutect2, varscan2
- SLC5A5 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs774861319; called by muse, varscan2
- SLC5A5 | c.1258A>G p.M420V | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1449767789; called by muse, mutect2, varscan2
- SLC7A8 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540015976, COSV57553238; called by muse, mutect2, varscan2
- SLC9A4 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54839669, COSV54840594; called by muse, mutect2, varscan2
- SLIT3 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.658); catalogued as rs373741690; called by muse, mutect2, varscan2
- SMARCC2 | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57225492; called by muse, mutect2, varscan2
- SMG5 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV52746801; called by muse, mutect2, varscan2
- SMTN | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762644399, COSV60778096; called by muse, mutect2, varscan2
- SNX25 | c.1716dup p.V573Sfs*7 | Frame Shift Ins (INS) | VAF 46/138 reads (33%) | catalogued as rs780499770; called by mutect2, varscan2
- SOGA1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.422); catalogued as rs1164956547; called by muse, mutect2
- SORBS1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as rs555941537, COSV53364551; called by muse, mutect2, varscan2
- SP140L | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.248); catalogued as rs756373352; called by muse, mutect2, varscan2
- SPAG17 | c.5185del p.T1729Lfs*21 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1400383672, COSV60464528; called by mutect2, pindel, varscan2
- SPATA20 | c.1195G>A p.A399T (on ENST00000356488 / NM_001258372.1; = p.A415T on NM_022827.4) | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs374270120; called by muse, mutect2, varscan2
- SPATA31D1 | c.2763G>C p.K921N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1262576899; called by muse, mutect2, varscan2
- SPNS1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs764766781; called by muse, varscan2
- SPPL2C | c.1856del p.P619Lfs*7 | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | catalogued as COSV100233975; called by mutect2, pindel, varscan2
- SPPL3 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV62232315; called by muse, mutect2, varscan2
- SPTA1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs772799574, COSV63749744, COSV63759526; called by muse, mutect2, varscan2
- SPTAN1 | c.1464G>A p.A488= | Splice Region (SNP) | VAF 229/728 reads (31%) | catalogued as rs749835470; called by muse, mutect2, varscan2
- SRCAP | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs768416540, COSV52682206; called by mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 117/346 reads (34%) | catalogued as rs748467821; called by mutect2, varscan2
- ST6GALNAC2 | c.949T>C p.C317R | Missense Mutation (SNP) | VAF 46/142 reads (32%) | PolyPhen probably damaging (1); catalogued as COSV56572759; called by muse, mutect2, varscan2
- STAB2 | c.6496C>T p.P2166S | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs780251305, COSV66347681; called by muse, mutect2, varscan2
- STARD8 | c.2028G>A p.W676* | Nonsense Mutation (SNP) | VAF 60/176 reads (34%) | catalogued as COSV52933462, COSV99367974; called by muse, mutect2, varscan2
- STK10 | c.2340G>A p.E780= | Splice Region (SNP) | VAF 30/113 reads (27%) | catalogued as rs1297701701; called by muse, mutect2, varscan2
- STUB1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567282437, COSV50208612; called by muse, mutect2, varscan2
- STXBP4 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs763528779, COSV64464665; called by muse, mutect2, varscan2
- SVIL | c.3679A>G p.T1227A (on ENST00000355867 / NM_021738.3; = p.T801A on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1420714988; called by muse, varscan2
- SYNCRIP | c.1614_1625del p.R539_A542del | In Frame Del (DEL) | VAF 98/461 reads (21%) | catalogued as rs1479615367; called by mutect2, varscan2
- SYNGAP1 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 175/552 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs764259746, COSV53380778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ2 | c.3832G>A p.V1278M | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.229); catalogued as rs199955411; called by muse, mutect2, varscan2
- TAF1C | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762537026; called by muse, mutect2, varscan2
- TAF1L | c.3671T>C p.F1224S | Missense Mutation (SNP) | VAF 113/369 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs761527217; called by muse, mutect2, varscan2
- TAT | c.236-2del p.X79_splice | Splice Site (DEL) | VAF 18/91 reads (20%) | catalogued as COSV63533168; called by mutect2, pindel, varscan2
- TAZ | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV50010316; called by muse, mutect2, varscan2
- TBC1D22A | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61438712; called by muse, mutect2, varscan2
- TBC1D9B | c.3512C>T p.A1171V (on ENST00000356834 / NM_198868.3; = p.A1154V on NM_015043.4) | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as rs774603201; called by muse, mutect2, varscan2
- TBCK | c.1588C>T p.R530C (on ENST00000273980 / NM_001163436.4; = p.R467C on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1267975131, COSV56755380; called by muse, mutect2, varscan2
- TBL1X | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs372248427; called by muse, varscan2
- TCL1A | c.345A>G p.*115Wext*15 | Nonstop Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV68086227; called by muse, mutect2, varscan2
- TECPR1 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778100283; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 92/352 reads (26%) | catalogued as rs753315680; called by mutect2, varscan2
- THBS1 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs775408471; called by muse, mutect2, varscan2
- THBS1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as rs760644149, COSV52952137; called by muse, mutect2, varscan2
- TICRR | c.4843A>C p.S1615R | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV51547351; called by muse, mutect2, varscan2
- TIGD2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745722561, COSV57648613; called by muse, mutect2, varscan2
- TIGIT | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 153/534 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs935162780; called by muse, mutect2, varscan2
- TIMELESS | c.3236_3238del p.F1079del | In Frame Del (DEL) | VAF 13/98 reads (13%) | catalogued as rs777135672; called by mutect2, pindel
- TMC2 | c.491del p.K164Rfs*18 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as rs775134383; called by mutect2, pindel, varscan2
- TMEM130 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs142570247, COSV59561389; called by muse, mutect2, varscan2
- TMEM132D | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1280927732, COSV67160048; called by muse, varscan2
- TMEM174 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.543); catalogued as rs1318635337, COSV57114372; called by muse, mutect2, varscan2
- TMEM184A | c.1019dup p.A341Gfs*83 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs747152549; called by mutect2, varscan2
- TNFRSF8 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as rs762490984; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3916G>A p.V1306M | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1466974206; called by muse, mutect2, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNRC6C | c.3568C>T p.R1190C | Missense Mutation (SNP) | VAF 141/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761429790; called by muse, mutect2, varscan2
- TPCN1 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as rs368409709; called by mutect2, varscan2
- TRABD | c.938A>C p.N313T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV57713076; called by muse, mutect2, varscan2
- TREML1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as rs767955129; called by muse, mutect2, varscan2
- TRIM72 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs140739096; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 35/152 reads (23%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPC6 | c.1128dup p.F377Ifs*17 | Frame Shift Ins (INS) | VAF 98/356 reads (28%) | catalogued as rs757446904; called by mutect2, varscan2
- TRPV2 | c.2186G>A p.G729D | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs547123940, COSV58427325; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs369782798; called by muse, mutect2, varscan2
- UBA5 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs150313260; called by muse, mutect2, varscan2
- UBE3B | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as rs1032357677; called by muse, mutect2, varscan2
- UCP1 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53768763; called by muse, mutect2, varscan2
- UNC79 | c.1183C>T p.R395C (on ENST00000393151 / NM_001346218.2; = p.R218C on NM_020818.5) | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs377687253; called by muse, mutect2, varscan2
- UNG | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54357088; called by muse, mutect2, varscan2
- USP2 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs756703374, COSV52727423; called by muse, mutect2, varscan2
- USP24 | c.2388del p.F796Lfs*4 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs1557629567; called by mutect2, pindel, varscan2
- USP26 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751525015, COSV63709689; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs764735138; called by mutect2, varscan2
- VAV3 | c.1970C>A p.P657H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58391044; called by muse, varscan2
- VRTN | c.983dup p.V329Rfs*25 | Frame Shift Ins (INS) | VAF 47/174 reads (27%) | catalogued as rs749358571; called by mutect2, varscan2
- VTI1A | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV101261071; called by muse, mutect2, varscan2
- VWA3A | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs746722541, COSV55392443; called by muse, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 57/190 reads (30%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WNT11 | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59445105; called by muse, mutect2, varscan2
- WNT3A | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1211326543; called by muse, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- XIRP1 | c.3587C>A p.P1196H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100453466; called by muse, varscan2
- XPO7 | c.1932G>A p.T644= | Splice Region (SNP) | VAF 124/456 reads (27%) | catalogued as rs780802638, COSV99380926; called by muse, mutect2, varscan2
- ZBTB11 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as COSV57245537; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV59691020; called by pindel, varscan2
- ZC3H6 | c.588dup p.Q197Tfs*11 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | catalogued as rs750386324; called by mutect2, varscan2
- ZEB1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754576407, COSV58040600; called by muse, mutect2, varscan2
- ZHX2 | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs148101741; called by muse, mutect2, varscan2
- ZNF142 | c.3755dup p.R1253Tfs*15 (on ENST00000411696 / NM_001379660.1; = p.R1053Tfs*15 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 23/92 reads (25%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF318 | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs377285454, COSV58931787; called by muse, mutect2, varscan2
- ZNF41 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as rs770494529; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 109/442 reads (25%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF644 | c.1121G>A p.S374N | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1347398368; called by muse, mutect2, varscan2
- ZNF677 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61720267; called by muse, varscan2
- ZNF775 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as rs550325399, COSV61613724; called by muse, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF99 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101234008; called by muse, mutect2, varscan2
- ZSCAN18 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1312642570, COSV53731737; called by muse, mutect2, varscan2
- ZSCAN2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 200/691 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs144452460; called by muse, mutect2, varscan2
- ABCA13 | c.3755A>G p.Q1252R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCB8 | c.839T>C p.V280A (on ENST00000297504 / NM_001282291.2; = p.V263A on NM_007188.5) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ABHD1 | c.956T>C p.I319T | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.4424dup p.T1476Hfs*7 | Frame Shift Ins (INS) | VAF 34/133 reads (26%) | called by mutect2, pindel, varscan2
- ACAD10 | c.2284G>A p.G762S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ACKR3 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACOT12 | c.1377A>C p.K459N | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ACVR2A | c.1231T>G p.Y411D | Missense Mutation (SNP) | VAF 131/422 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADAM18 | c.1822-1G>C p.X608_splice | Splice Site (SNP) | VAF 48/144 reads (33%) | called by muse, mutect2, varscan2
- ADAM29 | c.2101dup p.S701Kfs*2 | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | called by mutect2, varscan2
- ADAMTS9 | c.4741G>A p.V1581M | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2270A>T p.Q757L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADCY1 | c.1425del p.F475Lfs*14 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ADCY3 | c.2314A>G p.S772G | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADIPOR1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AHCTF1 | c.412G>T p.G138W (on ENST00000366508; = p.G112W on NM_015446.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AHCYL2 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- AHNAK | c.17327C>T p.P5776L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- AHNAK | c.3853G>A p.V1285I | Missense Mutation (SNP) | VAF 209/757 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AIDA | c.751del p.R251Gfs*22 | Frame Shift Del (DEL) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- ALKBH8 | c.326T>C p.L109S | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALOX5AP | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ALPK3 | c.2304del p.K768Nfs*12 | Frame Shift Del (DEL) | VAF 56/263 reads (21%) | called by mutect2, pindel, varscan2
- AMY2B | c.30dup p.G11Wfs*23 | Frame Shift Ins (INS) | VAF 62/559 reads (11%) | called by mutect2, pindel, varscan2
- ANK1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ANKS1A | c.1014T>C p.G338= | Splice Region (SNP) | VAF 51/201 reads (25%) | called by muse, mutect2, varscan2
- ANO5 | c.2468T>C p.M823T | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- AP002748.5 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 167/544 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- AP2A2 | c.1205dup p.Q403Tfs*14 | Frame Shift Ins (INS) | VAF 53/233 reads (23%) | called by mutect2, pindel, varscan2
- APEX2 | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARCN1 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP12 | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMCX5 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ARSI | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- ASPM | c.7857del p.K2619Nfs*22 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ATF6 | c.7dup p.E3? | Frame Shift Ins (INS) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- ATG5 | c.704del p.K235Rfs*4 | Frame Shift Del (DEL) | VAF 42/148 reads (28%) | called by mutect2, varscan2
- ATM | c.6908del p.K2303Rfs*7 | Frame Shift Del (DEL) | VAF 65/209 reads (31%) | called by mutect2, pindel, varscan2
- ATP12A | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 130/820 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP8A1 | c.2707A>G p.M903V | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AVPR1A | c.1053del p.F351Lfs*19 | Frame Shift Del (DEL) | VAF 86/321 reads (27%) | called by mutect2, pindel, varscan2
- B2M | c.204del p.V69Wfs*34 | Frame Shift Del (DEL) | VAF 152/567 reads (27%) | called by mutect2, pindel, varscan2
- B3GAT3 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- B3GLCT | c.823del p.T275Hfs*61 | Frame Shift Del (DEL) | VAF 59/345 reads (17%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.884T>G p.L295R | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL2L2 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- BCR | c.1772A>G p.Y591C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BDP1 | c.6107T>C p.V2036A | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, varscan2
- BFAR | c.763del p.Q255Rfs*9 | Frame Shift Del (DEL) | VAF 29/143 reads (20%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.3853T>C p.F1285L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- BMP4 | c.1095T>G p.N365K | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); called by muse, mutect2
- BOD1 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- BOK | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- BSND | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD5 | c.2025del p.D676Mfs*40 | Frame Shift Del (DEL) | VAF 81/295 reads (27%) | called by mutect2, pindel, varscan2
- CACNA1F | c.4724-1G>C p.X1575_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.1844A>G p.E615G | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CADPS2 | c.2466del p.I824* | Frame Shift Del (DEL) | VAF 46/246 reads (19%) | called by mutect2, pindel, varscan2
- CAND1 | c.2987A>G p.H996R | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- CAND2 | c.1484T>C p.I495T (on ENST00000456430 / NM_001162499.2; = p.I402T on NM_012298.3) | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CAPRIN1 | c.790T>C p.S264P | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPZA2 | c.836T>G p.I279S | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CARMIL1 | c.2980A>G p.K994E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CBLB | c.2125T>C p.Y709H | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- CCDC198 | c.487del p.R163Dfs*8 | Frame Shift Del (DEL) | VAF 100/328 reads (30%) | called by mutect2, pindel, varscan2
- CCDC73 | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 32/701 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CCDC78 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- CCDC92 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 140/440 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCL16 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCND3 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD180 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CD79B | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC25B | c.1628G>T p.R543L (on ENST00000245960 / NM_021873.3; = p.R529L on NM_004358.4) | Missense Mutation (SNP) | VAF 111/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC7 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.3809A>G p.Y1270C | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CDH23 | c.5872C>T p.L1958F | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CELF5 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CELSR1 | c.7363A>G p.M2455V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.6271A>G p.S2091G | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2
- CFAP43 | c.4140del p.V1381Wfs*7 | Frame Shift Del (DEL) | VAF 41/229 reads (18%) | called by mutect2, pindel, varscan2
- CFAP65 | c.4201C>A p.Q1401K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CHD1 | c.1085+2T>C p.X362_splice | Splice Site (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- CHD7 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 108/481 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD7 | c.4045A>G p.I1349V | Missense Mutation (SNP) | VAF 193/661 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CHMP7 | c.367del p.V123Lfs*6 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- CHRD | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); called by muse, mutect2
- CHST1 | c.1175A>T p.E392V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CHST4 | c.281del p.V94Gfs*4 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | called by mutect2, varscan2
- CHST4 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLUH | c.3753del p.D1252Tfs*5 (on ENST00000435359; = p.D1291Tfs*5 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- CNGB1 | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CNTN1 | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL14A1 | c.4285A>G p.T1429A | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A2 | c.2241G>T p.K747N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A1 | c.4741T>C p.Y1581H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A1 | c.1808dup p.G604Wfs*13 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by pindel, varscan2
- COL5A1 | c.2796del p.K933Rfs*141 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- COPRS | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CORO2B | c.872del p.X291_splice | Splice Site (DEL) | VAF 120/504 reads (24%) | called by mutect2, pindel, varscan2
- CPB2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- CPSF3 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CST9 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CSTF3 | c.364dup p.M122Nfs*6 | Frame Shift Ins (INS) | VAF 36/180 reads (20%) | called by mutect2, pindel, varscan2
- CTRL | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.6502C>T p.P2168S | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CUL1 | c.1397A>C p.Y466S | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2R1 | c.961T>C p.W321R | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCLRE1A | c.2691del p.V898Wfs*37 | Frame Shift Del (DEL) | VAF 87/312 reads (28%) | called by mutect2, pindel, varscan2
- DENND4A | c.966del p.F322Lfs*8 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- DENND5A | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DGKA | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DIDO1 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DIP2B | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- DLX5 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 128/461 reads (28%) | called by mutect2, pindel, varscan2
- DMWD | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DMWD | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNA2 | c.3158T>C p.I1053T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH17 | c.3364C>T p.L1122F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.4689dup p.P1564Tfs*5 | Frame Shift Ins (INS) | VAF 58/237 reads (24%) | called by mutect2, varscan2
- DNAJB13 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 85/224 reads (38%) | called by mutect2, varscan2
- DPP9 | c.2441del p.F814Sfs*10 (on ENST00000598800; = p.F843Sfs*10 on NM_139159.5) | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- DSEL | c.3407A>G p.K1136R | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DUOX2 | c.1448A>T p.E483V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DUS1L | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DYNC2I1 | c.1686T>A p.S562R | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- EDN1 | c.461del p.K154Sfs*7 | Frame Shift Del (DEL) | VAF 53/185 reads (29%) | called by mutect2, varscan2
- EGR2 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EIF2B5 | c.1837dup p.L613Pfs*9 (on ENST00000647909; = p.L605Pfs*9 on NM_003907.3) | Frame Shift Ins (INS) | VAF 40/184 reads (22%) | called by mutect2, pindel, varscan2
- EIF3A | c.3989T>C p.V1330A | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 64/212 reads (30%) | called by mutect2, varscan2
- EIF5 | c.1054A>G p.I352V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ELOVL7 | c.683T>C p.M228T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- EML5 | c.4963T>C p.C1655R (on ENST00000380664; = p.C1663R on NM_183387.3) | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- EPB41L4A | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- EPB41L4B | c.994_996del p.D332del | In Frame Del (DEL) | VAF 28/260 reads (11%) | called by pindel, varscan2
- EPHA3 | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 125/401 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by mutect2, varscan2
- ERBB4 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ERICH5 | c.700A>C p.S234R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ESF1 | c.295del p.T99Pfs*12 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- ESPL1 | c.2960T>C p.V987A | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ESPL1 | c.5643G>T p.Q1881H | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ESYT2 | c.1858C>A p.L620I (on ENST00000613624; = p.L544I on NM_020728.3) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by mutect2, varscan2
- ETAA1 | c.369dup p.Q124Tfs*7 | Frame Shift Ins (INS) | VAF 46/160 reads (29%) | called by mutect2, varscan2
- ETNPPL | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ETV4 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVC2 | c.1739dup p.Q581Pfs*3 | Frame Shift Ins (INS) | VAF 58/241 reads (24%) | called by mutect2, pindel, varscan2
- EXOSC5 | c.615+1G>A p.X205_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- EXTL3 | c.2507T>C p.M836T | Missense Mutation (SNP) | VAF 129/436 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAF2 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM114A1 | c.998del p.N333Mfs*3 | Frame Shift Del (DEL) | VAF 41/147 reads (28%) | called by mutect2, pindel, varscan2
- FAM120B | c.892del p.Y298Ifs*24 | Frame Shift Del (DEL) | VAF 58/219 reads (26%) | called by mutect2, pindel, varscan2
- FAM90A1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FAT1 | c.10856G>A p.G3619E | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN3 | c.7731del p.T2578Pfs*120 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- FBXL18 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO10 | c.1805dup p.G603Rfs*15 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- FBXO30 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 67/629 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF16 | c.514del p.R172Gfs*20 | Frame Shift Del (DEL) | VAF 58/216 reads (27%) | called by mutect2, pindel, varscan2
- FILIP1L | c.2192C>T p.A731V (on ENST00000354552 / NM_182909.3; = p.A491V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.658); called by muse, varscan2
- FLNA | c.5830C>A p.P1944T (on ENST00000369850 / NM_001110556.2; = p.P1936T on NM_001456.3) | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- FNBP4 | c.2368_2369del p.K790Efs*7 | Frame Shift Del (DEL) | VAF 62/214 reads (29%) | called by mutect2, pindel, varscan2
- FNIP1 | c.1598A>G p.Q533R | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FOXG1 | c.560A>C p.N187T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1358A>G p.D453G | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.272); called by muse, varscan2
- FREM2 | c.4711A>G p.T1571A | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- FRMPD4 | c.2924C>A p.P975Q | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FRY | c.2610dup p.T871Hfs*25 | Frame Shift Ins (INS) | VAF 50/265 reads (19%) | called by mutect2, pindel, varscan2
- FRY | c.7500G>T p.E2500D | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- FURIN | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FXR1 | c.371dup p.N124Kfs*5 | Frame Shift Ins (INS) | VAF 48/172 reads (28%) | called by mutect2, varscan2
- FYB1 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FZD2 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G2E3 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- G3BP1 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 177/567 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GAA | c.2471T>C p.I824T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- GABRA3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GABRG3 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALR1 | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GATA1 | c.1203dup p.T402Hfs*48 | Frame Shift Ins (INS) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- GBP1 | c.1297T>C p.Y433H | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.63); called by muse, mutect2
- GDPD2 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GET1 | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GGT1 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- GJA10 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 110/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GJA4 | c.954del p.K318Nfs*90 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | called by mutect2, varscan2
- GJB1 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLRA4 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 229/780 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR50 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 272/929 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
677 further variants in this file (336 protein-altering or splice-affecting, 317 silent, 24 other) are not listed here.
